Surgical pathology report (de-identified scan), TCGA case TCGA-XU-AAXV, project TCGA-THYM (Thymoma), tissue source site University Health Network, specimen TCGA-XU-AAXV-01A (Primary Tumor).

[page 1 of 2]
ICD-3
Thymoma, Type B2, malignant
858413
Site: Thymoma C379
QW 6/21/14

Patient Name:

MRN:

DOB: (Age:)

Gender: F

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Thymus: thymus gland and thymoma stitch on right pleura and right lower pole

DIAGNOSIS

1. Thymus gland

a) Thymoma exhibiting focal minimal microscopic invasion into immediately adjacent extra-capsular connective tissue.

See comment.

b) Margins of specimen - No tumor involvement.

c) Adjacent non-neoplastic thymus

i) Involutional changes consistent with patient's age

ii) No significant lymphoid hyperplasia

COMMENT

Examination of this material indicates apparent complete resection of a 5.5 cm thymoma of Predominantly mixed (Lattes/Bernatz)/Cortical (Muller Hermelink)/Type B2 (WHO) type. In a couple of areas there is minimal direct extension beyond the confines of the external capsule into the immediately adjacent fibroadipose tissue. The external margins of the specimen as indicated by prior AgNO3 application are clear of tumor involvement.

ELECTRONICALLY VERIFIED BY:

CLINICAL HISTORY

Mediastinal tumour

GROSS DESCRIPTION

The specimen container labeled with the patient's name and as "thymus gland and thymoma stitch on right pleura and right lower pole", contains

Status: complete

Page: 1 of 2

[page 2 of 2]
Patient Name:

MRN:

DOB:

Gender: F

Age:)

Service:

Visit #:

Location:

Facility:

Collected:

Resulted:

Ordering MD:

a portion of fatty tissue with a firm lobular mass at one end and oriented with a stitch on the right pleura. The entire specimen measures 12.0 cm. SI x 4.5 cm ML x 3.0 cm AP. The lobular mass measure 5.5 cm SI x 4.5 cm ML x 3.0 cm AP. The mass is within the lower pole and the anteriorly covered by smooth shiny membrane. The entire specimen surfaces are painted with silver nitrate. On sectioning the cut surface of the mass is solid and homogenous yellowish-white. The rest of the tissue is grossly unremarkable thymic tissue. Sections are submitted as follows:

1A-1C lobular mass with anterior surface

1D-1F lobular mass with posterior surface

1G-1I superior pole grossly normal tissue

Status: complete

Page: 2 of 2

Source: NCI Genomic Data Commons file d78b74ad-7402-45ae-afcb-64cc8752d92b (TCGA-XU-AAXV.E4A9585C-1D65-4C42-BF09-78573DAC5A71.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).